Surgical pathology report (de-identified scan), TCGA case TCGA-06-1806, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-1806-01A (Primary Tumor).

[page 1 of 5]
Pathology and Laboratory Medicine

Surgical Pathology Report

TCGA-06-1806

CLINICAL HISTORY

_____ has two weeks history of _____ with normal EEG. On imaging there is a calcified enhancing lesion in the left temporal lobe. The lesion has a broad leptomeningeal base towards the lateral wall of the middle cranial fossa, and solid areas of enhancement with septation. The lesion also has chronic hemorrhage products, and absence of vasogenic edema or mass effect.

OPERATIVE DIAGNOSES

Left temporal lesion

Operation/Specimen: A: Brain, left temporal tumor, biopsy
B: Brain, left temporal tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A, B. Brain, left temporal tumor, excision: Astrocytic neoplasm with anaplastic features.
See Microscopy Description and Comment.

COMMENT

The neoplasm is a superficial pleomorphic glial neoplasm that is in close contact with the leptomeninges. The bulk of the tumor has mostly oligo-like/astrocytic and spindle/fascicular growth components. There are also a few focal areas that are densely epithelioid and have a sarcomatoid appearance. The oligoastrocytic and spindle cell components of the tumor appear to be low histological grade. The solid epithelioid component, however, has readily found mitotic figures and a high MIB-1 proliferation index of up to 25%. There is prominent hemosiderosis and some micro mineralization focally.

The findings may possibly be interpreted as those of a superficial, pleomorphic glial neoplasm with morphological features of a pleomorphic xanthoastrocytoma that has focal zones of anaplastic transformation. A superficial glioblastoma is an important differential diagnosis.

The case is being sent for an outside opinion.

** Electronically Signed Out***

Senior Staff Pathologist

[page 2 of 5]
Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from paraffin tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1592, D1S552, D19S606 and D19S1182

Results-Comments

Test performed on DNA extracted from paraffin block and peripheral blood for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as

[page 3 of 5]
required by CLIA ' regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

TCGA-06-1806

INTRA-OPERATIVE CONSULTATION

A.
Brain, left temporal tumor, biopsy, touch prep and smears: Glial neoplasm (suggestive of ependymoma, but atypical location, probably high grade. Not an oligodendroglioma). Touch preparation smears performed at Hospital and results reported to the Physician of Record.

Senior Staff Pathologist

GROSS DESCRIPTION

A.
"Left temporal tumor," received fresh, one fragment, 1.5 x 1.0 x 0.3 cm. Soft, diffuent, greyish-red. In total, A1 and A2. Two paraffin blocks from the Hermelin Tumor Tissue Bank (3 and 7) are labelled A6 and A7.

B.
"Left temporal tumor", received fresh one fragment, 1.5 x 1.5 x 0.3 cm. Soft, greyish-red and area with pale appearance. In total, B1 and B2.

MICROSCOPIC DESCRIPTION

H and IMMUNOHISTOCHEMISTRY: The lesion is a pleomorphic glial neoplasm.

There are glial areas with oligodendroglioma-like and astrocytoma phenotypes. These areas appear as low histological grade. There are also extensive areas that have a spindle cell/fascicular growth morphology, in some of which the cytoplasm appears vacuolar ("xanthomatous"). Furthermore, there are fragments that have epithelioid, plump cell morphology with nuclear pleomorphism. There is transition between the three different patterns. Microvascular proliferation and necrosis are rather inconspicuous.

The GFAP demonstrates that in all three different areas there is an appreciable population of gliofibrillary-positive cells. The reticulum demonstrates that throughout the tumor and in between the neoplastic glial cells there is a rich intercellular reticulin network, which is particularly prominent in the spindle cell and epithelioid areas.

The neuronal markers (NeuN and synaptophysin) highlight portions of cerebral cortex and native neurons entrapped by neoplastic tissue; there does not

[page 4 of 5]
appear to be a neuronal neoplastic component.

Mitotic figures are inconspicuous in the glial and spindle/fascicular zones of the neoplasm, where the MIB-1 proliferation indices are very low overall. However, in a couple of areas of compact epithelioid pattern, mitotic figures can be identified without difficulty and the MIB-1 proliferation index is high, about 25% (A1 and A7).

The neoplasm is superficial, focally in contact with the pia, and has multifocal collections of lymphocytes. Throughout the tumor there are abundant deposits of hemosiderin. This hemosiderosis is readily identified in xanthomatous areas. There are also focal areas of micro mineralization. On the smears there is prominent microvascular proliferation with frequent formation of glomeruloid structures.

ICD-9(s):
239.6 239.6

TCGA-06-1806

Histo Data

Part A: Brain, left temporal tumor, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
mGFAP-DA x 1		1		
H/E x 1		1		
KeratinSu x 1		1		
MJ-DA x 1		1		
P1 J7 x 1		1		
Retic x 1		1		
TPS H/E x 1		1		
M Trich x 1		1		
Vim-DA x 1		1		
H/E x 1		2		
H/E x 1		3		
H/E x 1		4		
H/E x 1		5		
CD31-DA x 1		6		
CD34-DA x 1		6		
CKit-DA x 1		6		
Desmin-DA x 1		6		
EMA-DA x 1		6		
mGFAP-DA x 1		6		
H/E x 1		6		
MGMT-curls x 1		6		
Thanks.				
MIB1-DA x 1		6		
PAS x 1		6		
PAS d x 1		6		
Retic x 1		6		
mGFAP-DA x 1		7		
H/E x 1		7		
Iron x 1		7		
MIB1-DA x 1		7		
NeuN x 1		7		
PAS x 1		7		
PAS d x 1		7		
Sy-DA x 1		7		

Do LOH also, please.

[page 5 of 5]
Part B: Brain, left temporal tumor, biopsy

Taken:	[REDACTED]	Received:	[REDACTED]	
Stain/cnt		Block	Ordered	Comment
H x 1		1	[REDACTED]	

*** End of Report ***

TCGA-06-1806

Source: NCI Genomic Data Commons file e22bdb80-e82a-410a-a0bc-0955e7c5f0dd (TCGA-06-1806.5B8C6B1F-DEEF-489E-BA9C-41088CA2ED87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).